MMRF case MMRF_1882 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4ebeb9ca-7d05-4a4c-9844-c063a96b4442

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.1 years (24,522 days); ISS stage: III; Days to last known disease status: 994 days (2.7 years); Days to last follow up: 994 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 30 days; Days to treatment end: 562 days (1.5 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 37 days; Days to treatment end: 268 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 93 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 134 days; Days to treatment end: 268 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 280 days; Days to treatment end: 562 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 29.6 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 21 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 5.87 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 504 µmol/L; Blood Urea Nitrogen 21.1 mmol/L; Calcium 2.15 mmol/L; Albumin 29 g/L; Total Protein 8.3 g/dL; Glucose 6.33 mmol/L; C-Reactive Protein 5.45 mg/dL.
- Day 64: Serum Free Immunoglobulin Light Chain, Kappa 5.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Hemoglobin 6.94 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.41 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 420 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 5.83 mmol/L.
- Day 268 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 8.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.65 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 376 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 8.25 mmol/L.
- Day 364 (ECOG 2): M Protein 1.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 15 g/L; Beta 2 Microglobulin 0.7 µg/mL; Hemoglobin 7.69 mmol/L; Leukocytes 5.5 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 446 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.03 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 25.4 mmol/L.
- Day 443 (ECOG 2): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.09 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 3.34 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 373 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL; Glucose 9.57 mmol/L.
- Day 534 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 14.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.43 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.57 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 425 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 12.3 mmol/L.
- Day 618 (ECOG 2): Immunoglobulin G 14.1 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 0.4 µg/mL; Hemoglobin 7.19 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.26 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 417 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 7.3 g/dL; Glucose 18.1 mmol/L.
- Day 709 (ECOG 2): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.81 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 0.3 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.82 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 461 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 11.3 mmol/L.
- Day 800 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.1 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 0.3 µg/mL; Hemoglobin 6.01 mmol/L; Leukocytes 5.6 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 460 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 8.86 mmol/L.
- Day 905 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.88 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 0.2 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.61 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 584 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 8.86 mmol/L.
- Day 994 (ECOG 2): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.86 mg/dL; Immunoglobulin G 18.1 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 0.3 µg/mL; Hemoglobin 6.51 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 477 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL; Glucose 7.98 mmol/L.

Other clinical attributes
- Day 1: Weight: 112 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1882_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1882_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
